Surgical pathology report (de-identified scan), TCGA case TCGA-44-7667, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7667-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

Date Coll: [REDACTED]

SPECIMEN

- A. Level 9 lymph node
- B. Sixth rib
- C. Level 11 lymph
- D. Right lower lobe
- E. Level 12 lymph node
- F. Level 7 lymph node
- G. Level 4 lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right lung mass.

GROSS DESCRIPTION

A. Received in formalin, labeled "level 9 lymph node" is a 0.4 x 0.3 x 0.2 cm slightly rubbery gray black tissue which is submitted in toto. AS-1.

B. Received fresh, labeled "sixth rib" is a 15.5 cm slightly curved tan white portion of bone ranging from 1.2 to 1.5 cm in diameter. The specimen is in keeping with rib. Representative sections are submitted in one block following fixation and decalcification. RS-1.

C. Received in formalin, labeled "level 11 lymph node" are three slightly rubbery tan red-gray tissues in keeping with lymph nodes measuring up to 1.3 cm in greatest dimension. The largest tissue is bisected and the specimens are entirely submitted in two blocks as labeled. AS-2.

BLOCK SUMMARY: 1 - Two whole nodes; 2 - bisected largest node.

D. Container D is labeled with the patient's name, medical record number and right lower lobe. The right lower lobe weighs 549.3 grams and measures 18 x 13 x 10 cm. in greatest dimensions. The pleural surface is stretched taught over a rounded mass. When incised the mass measures 15 x 9 x 10 cm. in greatest dimensions. The mass does not appear to invade through the pleural surface. The center of the mass is markedly necrotic. The periphery of the mass is firm, tan and fleshy. The mass comes to within 0.5 cm. of the bronchial margin. The remainder of the pulmonary parenchyma is spongy and beefy red. RSD1 - Bronchial margin; D2-D7 - representative sections of the tumor; D8 - uninvolved lung parenchyma.

E. Received in formalin, labeled "level 12 lymph node" are five slightly rubbery gray black tissues ranging from 0.25 to 0.6 cm in greatest dimension which are submitted in toto. AS-1.

F. Received in formalin, labeled "level 7 lymph node" are three diffusely cauterized rubbery gray black tissues ranging from 0.6 to 2.8 cm in greatest dimension. The specimens are entirely submitted in three blocks as labeled. [REDACTED].

BLOCK SUMMARY: 1 - Two whole tissues; 2 & 3 - sections of largest tissue.

G. Received in formalin, labeled "level 4 lymph node" are two rubbery gray black-tan tissues in keeping with lymph nodes averaging 0.9 cm in greatest dimension. The specimens are bisected and entirely submitted independently in two blocks. [REDACTED].

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

- A. The sections of the level 9 lymph node demonstrate 1 lymph node with no evidence of metastatic disease.
- B. The rib is unremarkable.
- C. Level 11 lymph nodes demonstrate no evidence of metastasis in 5 lymph nodes.
- D. Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Primary tumor (pT): 15 cm., pT3
Margins of resection: Negative
Direct extension of tumor: Not identified.
Venous (large vessel) invasion: Suspicious
Arterial (large vessel) invasion: Suspicious
Lymphatic (small vessel) invasion: Suspicious
Regional lymph nodes (pN): Negative as described in other specimens (pNO)
Distant metastasis (pM): Can not be evaluated by this specimen (pMX).
Other findings: None
- E. There is no evidence of metastasis in five level 12 lymph nodes. F. There is no evidence of metastasis in eight level 7 lymph nodes. G. There is no evidence of metastasis in three level 4 lymph nodes.

[REDACTED]

DIAGNOSIS

- A. Level 9 lymph node, resection:
No evidence of metastasis in one lymph node (0/1).
- B. Sixth rib, resection:
Unremarkable bone present.
- C. Level 11 lymph nodes, resection:
No evidence of metastasis to 5 lymph nodes (0/5).
- D. Lung, right lower lobe, lobectomy:
Adenocarcinoma, poorly differentiated, 15 cm. in greatest dimension, surgical margins uninvolved.
- E. Level 12 lymph nodes, resection:
No evidence of metastasis to 5 lymph nodes (0/5).
- F. Level 7 lymph nodes, resection:
No evidence of metastasis to 8 lymph nodes (0/8).
- G. Level 4 lymph nodes, resection:
No evidence of metastasis to 3 lymph nodes (0/3).
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file a6994824-885a-48c7-87b6-8b8cf8dbeb6e (TCGA-44-7667.9722E13C-6AC6-415B-A84F-997D301CEA49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).